Surgical pathology report (de-identified scan), TCGA case TCGA-IF-A3RQ, project TCGA-SARC (Sarcoma), tissue source site University of Texas MD Anderson Cancer Center, specimen TCGA-IF-A3RQ-01A (Primary Tumor).

[page 1 of 2]
Specimen Date/Time:

** Case imported from computer system. The format of this report does not match the original case. **
** For cases prior to the section "SPECIMEN" may have been added. **

DIAGNOSIS

- (A) RETROPERITONEAL TUMOR:
DEDIFFERENTIATED LIPOSARCOMA IN A BACKGROUND OF ATYPICAL LIPOMATOUS TUMOR. (SEE COMMENT)
ATYPICAL LIPOMATOUS TUMOR INVOLVING SUPERIOR MARGIN.
- (B) SUPERIOR MARGIN:
ADIPOSE TISSUE WITH FIBROUS AREAS WITH SLIGHTLY ATYPICAL CELLS
SUGGESTIVE OF ATYPICAL LIPOMATOUS TUMOR.
- (C) LIVER BIOPSY:
Bile duct hamartoma..
No evidence of malignancy.

Entire report and diagnosis completed by:
Report released by:

ICD03
liposarcoma,
ckdifferentiated
8858/3
Site: retroperitoneum
C48.0 3/27/12
RD

COMMENT

The retroperitoneal tumor (specimen A) measures 15.0 cm in greatest dimension and is composed mostly of a dedifferentiated liposarcoma which is arising in a background of atypical lipomatous tumor.

GROSS DESCRIPTION

(A) RETROPERITONEAL TUMOR - Consists of a well-circumscribed, grossly encapsulated yellow nodular mass (15.0 x 12.0 x 6.0 cm). The tumor shows focal areas of yellow necrosis which represents 5-10 percent of the mass. The tumor is surrounded by a thin fibrous capsule which measures less than 2.0 mm in diameter.

INK CODE: BLACK - deep; blue - superior/inferior; yellow - lateral/paraspinal; green - medial; red - superficial.

SECTION CODE: Representative sections are submitted as follows. A1, tumor for frozen section; A2-A5, superior margin; A6, superficial; A7, deep margin; A8, paraspinal/lateral; A9, medial; A10, inferior margin; A11-A18, random sections of tumor.

*FS/DX: SARCOMA CONSISTENT WITH DEDIFFERENTIATED LIPOSARCOMA.

(B) RIGHT SUPERIOR MARGIN - A portion of adipose tissue (1.5 x 1.0 x 0.5 cm). No gross pathology identified. Entire specimen submitted for frozen section as B.

*FS/DX: ADIPOSE TISSUE WITH FOCAL ATYPIA; IT COULD REPRESENT ATYPICAL LIPOMATOUS TUMOR. DEFINITIVE DIAGNOSIS DEFER TO PERMANENT.

(C) LIVER BIOPSY - A 0.5 x 0.4 x 0.2 cm irregular piece of rubbery white-pink tissue which is bisected and submitted in toto as C.

SNOMED CODES

M-88583 T-D4900

-----END OF REPORT-----

[page 2 of 2]
Specimen Date/Time:

Source: NCI Genomic Data Commons file b9b9e958-d365-4b12-a672-7f6f1cf83ec3 (TCGA-IF-A3RQ.88F2969D-41F0-4019-AB2A-B90784E73162.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).